Gene-level copy-number profile of tumor specimen TCGA-2J-AAB8-01A from TCGA case TCGA-2J-AAB8, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.3 years (26,028 days).
Specimen TCGA-2J-AAB8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.e24021a5-fe0b-45fa-9f60-f7cec58a17db.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AAB8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 396 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bba61d73-a907-4683-88f0-f955ef4609bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,692; copy number 1: 15,709; copy number 2: 37,335; copy number 3: 3,030; copy number 4: 309; copy number 5: 12; copy number 6: 61; copy number 8: 78; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2J-AAB8-01A-12D-A40V-01): tumor purity 0.29, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 773 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,275,298–90,221,384, 48 genes: IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, AC006453.3, LSP1P5, 5S_rRNA, AC006453.1, AC006453.2, AC006453.4, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr3:8,775,402–8,963,773, 3 genes (within-gene range 0–1): RAD18, AC034186.2, AC034186.1.
- chr3:9,014,123–9,104,078, 2 genes: SRGAP3-AS1, AC037193.1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr18:30,290,161–80,247,514, 718 genes (broad region; genes not listed).
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 152 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 8 (within-gene range 2–8): AC244205.1.
- chr2:88,857,161–89,268,506, 41 genes, copy number 8: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.
- chr3:110,888,384–111,071,553, 1 gene, copy number 9 (within-gene range 2–9): NECTIN3-AS1.
- chr3:127,322,307–128,153,914, 21 genes, copy number 6 (within-gene range 1–6): LINC02016, LINC01471, AC016968.1, LINC02034, AC084035.1, TPRA1, MIR6825, MIR7976, MCM2, AC023593.1, PODXL2, ABTB1, MGLL, AC117480.1, KBTBD12, RNA5SP139, SEC61A1, RUVBL1, RNU2-37P, RUVBL1-AS1, RNU6-823P.
- chr3:128,181,402–128,194,452, 1 gene, copy number 6: AL449214.1.
- chr3:130,560,334–131,016,712, 11 genes, copy number 8 (within-gene range 1–8): COL6A6, PIK3R4, RN7SKP212, AC097105.1, GSTO3P, ATP2C1, AC055733.4, AC055733.2, Y_RNA, AC055733.1, AC055733.3.
- chr3:169,613,510–170,860,993, 41 genes, copy number 6–8 (within-gene range 2–8): AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2.
- chr4:41,220,074–41,824,119, 12 genes, copy number 5 (within-gene range 1–5): UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P.
- chr6:140,845,958–141,404,494, 4 genes, copy number 6: AL035446.1, AL357084.1, AL357080.1, AL355596.2.
- chr8:40,530,590–41,309,473, 8 genes, copy number 8 (within-gene range 2–8): ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P.
- chr12:7,812,512–7,976,360, 11 genes, copy number 6 (within-gene range 2–6): SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 15,696. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
